TCGA case TCGA-13-1498 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56a30462-2819-4c18-95be-8e73880a4921

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 2,012 days (5.5 years); Population group: Ashkenazi Jew.

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Classification of tumor: primary; Age at diagnosis: 73.4 years (26,820 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Residual tumor measurement: >20 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 216 days; Number of cycles: 10; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 7 days; Days to treatment end: 216 days; Number of cycles: 10; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Adjuvant; Days to treatment start: 250 days; Days to treatment end: 632 days (1.7 years); Treatment dose: 3 mg.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 74.9 years (27,354 days); Days to diagnosis: 534 days (1.5 years); Prior treatment: Yes.
3. Progression of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 74.9 years (27,354 days); Days to diagnosis: 534 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 534 (post initial treatment): Progression or recurrence: Yes; Days to progression: 534 days (1.5 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,144 days (3.1 years); Disease response: With Tumor.
- Days to follow up: 2,012 days (5.5 years); Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-1498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-13-1498-01A-01-BS1: Section location: Bottom; Percent tumor cells: 94; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 5.
  Slide TCGA-13-1498-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-13-1498-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Jewish religion heritage indicator: Ashkenazi; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Femara.
- Follow-up form 1: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,012 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,012 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 534 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-1498-01A-01D-0472-01): tumor purity 0.89, ploidy 1.95, whole-genome doublings 0.
